Somatic mutation profile of tumor specimen ALCH-B0B6-TTP1-A (aliquot ALCH-B0B6-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0B6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.9 years (24,425 days).
Specimen ALCH-B0B6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79e22dc7-582b-448d-bc60-f91279c1c16c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0B6-NB1-A (Blood Derived Normal), aliquot ALCH-B0B6-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef34447f-983c-4e0b-93c1-7d26def2e47c

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Intron 4, Splice Site 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.3184C>T p.R1062W | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53122041; called by muse, mutect2
- CDH2 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV52277714, COSV52283279; called by muse, mutect2
- EGFR | c.2239_2251delinsC p.L747_T751delinsP | In Frame Del (DEL) | VAF 74/535 reads (14%) | catalogued as rs397509368, COSV51765856; ClinVar: drug response; called by pindel, varscan2*
- GABRP | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs578165631; called by muse, mutect2
- LMTK2 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.636); catalogued as rs754515637, COSV51995121; called by mutect2, varscan2
- MAGEA12 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs199979249, COSV100757106, COSV63294436; called by muse, mutect2
- MYOC | c.1430T>C p.I477T | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as CM971026, CM981352; called by muse, mutect2, varscan2
- PWP1 | c.406-3T>G | Splice Region (SNP) | VAF 12/132 reads (9%) | catalogued as rs1259477434; called by muse, mutect2
- SRPRA | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1170905226, COSV99703198; called by muse, mutect2
- TUFM | c.1187C>G p.P396R | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV57948760; called by muse, mutect2
- BTG4 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2
- GABRA6 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 99/532 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGF1R | c.3532T>A p.W1178R | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNAB2 | c.416-1G>T p.X139_splice | Splice Site (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- KRT83 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 34/424 reads (8%) | called by muse, mutect2
- OSBPL6 | c.2436T>G p.I812M | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TANC2 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2
- ZNF827 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CEPT1 | c.369C>T p.A123= | Silent (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- CYSLTR1 | c.375T>C p.I125= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- DACT1 | c.2049C>T p.A683= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs761824658; called by muse, mutect2, varscan2
- SALL3 | c.117C>T p.S39= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs146469887; called by muse, mutect2
- SMAD6 | c.93T>C p.G31= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs780659575; ClinVar: likely benign; called by mutect2, varscan2
- TNN | c.2586G>C p.T862= | Silent (SNP) | VAF 25/241 reads (10%) | called by muse, mutect2, varscan2
- USH2A | c.14073C>T p.N4691= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs370364142, COSV56342993; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATRX | c.4810-48A>T | Intron (SNP) | VAF 12/176 reads (7%) | catalogued as rs1557106813, COSV64872310; called by muse, mutect2
- EGFLAM | c.713-2273T>C | Intron (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- RALGPS1 | c.216+12182A>T | Intron (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- SEC16B | c.999-23C>A | Intron (SNP) | VAF 39/375 reads (10%) | called by muse, mutect2, varscan2
